Somatic mutation profile of tumor specimen 1105227 (aliquot 7316UP-662-1105227) from CPTAC case C204057, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105227: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecc7688d-8656-42b6-b397-191361712bc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105284 (Blood Derived Normal), aliquot 7316UP-302-1105284; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0b5b397-cf38-41c9-b592-01916b808e1a

The open-access MAF lists 85 somatic variants for this specimen: 50 protein-altering or splice-affecting, 26 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 26, Nonsense Mutation 4, Intron 4, Frame Shift Del 3, 3'UTR 3, Splice Site 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 38/457 reads (8%) | hotspot (GDC flag); catalogued as rs778405030, CM950845, COSV62197118; ClinVar: pathogenic; called by muse, mutect2
- PTPN11 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 76/543 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM043070, CM052358, COSV61008620; called by muse, mutect2, varscan2
- AHDC1 | c.1945G>C p.A649P | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.083); catalogued as CD1515401; called by muse, mutect2, varscan2
- ALAS1 | c.1330+1G>A p.X444_splice | Splice Site (SNP) | VAF 9/130 reads (7%) | catalogued as rs1469355365; called by muse, mutect2
- ARMCX2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs782307127, COSV100168205; called by muse, mutect2, varscan2
- CBLL2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100081584; called by muse, mutect2, varscan2
- CDH9 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 43/163 reads (26%) | catalogued as rs779923057, COSV50275360, COSV50343795; called by muse, mutect2, varscan2
- COL6A3 | c.6470C>T p.P2157L | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372281922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CR1 | c.2606T>C p.I869T | Missense Mutation (SNP) | VAF 75/507 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV65456805; called by muse, mutect2, varscan2
- DGKQ | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 84/240 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs752503518, COSV53281525; called by muse, mutect2, varscan2
- DSG2 | c.2084C>T p.T695M | Missense Mutation (SNP) | VAF 133/418 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs200137091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENPP2 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.821); catalogued as rs377608124; called by muse, mutect2, varscan2
- FLG | c.10204C>T p.R3402W | Missense Mutation (SNP) | VAF 242/795 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs141655789; called by muse, mutect2, varscan2
- HECW1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335374674, COSV67836832, COSV67837728; called by muse, mutect2, varscan2
- IQCF1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 157/570 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs752889161, COSV58823372; called by muse, mutect2, varscan2
- KCNB2 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 36/231 reads (16%) | catalogued as rs748825911, COSV73048736; called by muse, mutect2, varscan2
- KCNQ5 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763071667; called by muse, mutect2, varscan2
- KIN | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as rs201258955; called by muse, mutect2, varscan2
- LILRA4 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749644963, COSV52492535; called by muse, mutect2, varscan2
- OR52B6 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756504887; called by muse, mutect2, varscan2
- PPP1R3F | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 199/718 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs782455380; called by muse, mutect2, varscan2
- PRKAG2 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 152/640 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs200392688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PWWP3B | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1250645990; called by muse, mutect2, varscan2
- RBBP8NL | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780896548; called by muse, mutect2, varscan2
- RELB | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs775189147, COSV55508233; called by muse, mutect2, varscan2
- SLC6A8 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 110/428 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs782326194; called by muse, mutect2, varscan2
- SSPN | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 119/451 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs745893300; called by muse, mutect2, varscan2
- ANOS1 | c.1355-2A>G p.X452_splice | Splice Site (SNP) | VAF 119/446 reads (27%) | called by muse, mutect2, varscan2
- CRYBG2 | c.1757del p.P586Lfs*15 | Frame Shift Del (DEL) | VAF 74/306 reads (24%) | called by mutect2, varscan2
- DDAH1 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- ELF3 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- HCFC1 | c.5141C>T p.T1714I | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HGS | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH5 | c.2200C>A p.L734I | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNQ3 | c.1082A>G p.E361G | Missense Mutation (SNP) | VAF 168/567 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- KIFC3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- LILRB2 | c.763G>T p.V255F | Missense Mutation (SNP) | VAF 93/586 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, varscan2
- MAP7D2 | c.1607A>G p.E536G | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MCF2 | c.1856A>G p.K619R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- MPPED2 | c.329A>C p.Y110S | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- NF1 | c.7924_7925del p.Y2642Lfs*17 (on ENST00000358273 / NM_001042492.3; = p.Y2621Lfs*17 on NM_000267.3) | Frame Shift Del (DEL) | VAF 51/368 reads (14%) | called by mutect2, pindel, varscan2
- NRK | c.2620G>T p.G874* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2
- OR5M1 | c.820A>C p.T274P | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PITPNM1 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 95/346 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPS3A | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SLITRK6 | c.1772C>A p.T591K | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- THAP9 | c.1714del p.L572* | Frame Shift Del (DEL) | VAF 24/147 reads (16%) | called by mutect2, pindel, varscan2
- UIMC1 | c.58_60del p.K20del | In Frame Del (DEL) | VAF 36/178 reads (20%) | called by pindel, varscan2
- WAPL | c.2085A>T p.R695S | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF195 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CDH7 | c.1965C>T p.D655= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs116347805, COSV59889152; called by muse, mutect2, varscan2
- CLCN5 | c.42T>C p.Y14= | Silent (SNP) | VAF 24/283 reads (8%) | catalogued as rs1557191337; called by muse, mutect2
- CLCNKB | c.1941C>A p.L647= | Silent (SNP) | VAF 26/367 reads (7%) | called by muse, mutect2
- CYP4F3 | c.315C>G p.T105= | Silent (SNP) | VAF 42/134 reads (31%) | catalogued as COSV99658828; called by muse, mutect2, varscan2
- DCAF12L2 | c.306G>A p.A102= | Silent (SNP) | VAF 64/339 reads (19%) | catalogued as COSV63582487, COSV63584428; called by muse, mutect2, varscan2
- EXPH5 | c.4192T>C p.L1398= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs376155497; called by muse, mutect2, varscan2
- FAM83E | c.1101G>A p.P367= | Silent (SNP) | VAF 21/233 reads (9%) | catalogued as rs532162334; called by muse, mutect2
- FERMT1 | c.423G>A p.P141= | Silent (SNP) | VAF 41/133 reads (31%) | catalogued as rs41308076; called by muse, mutect2, varscan2
- FLNC | c.2271C>T p.N757= | Silent (SNP) | VAF 53/178 reads (30%) | catalogued as rs779105468; called by muse, mutect2, varscan2
- IGKV1D-42 | c.81C>A p.T27= | Silent (SNP) | VAF 54/251 reads (22%) | called by muse, mutect2, varscan2
- KMT2E | c.3537T>C p.F1179= | Silent (SNP) | VAF 61/230 reads (27%) | catalogued as rs137965134; called by muse, mutect2, varscan2
- NAA40 | c.588C>T p.D196= | Silent (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.246T>C p.G82= (on ENST00000259318 / NM_001136562.3; = p.G313= on NM_007203.5) | Silent (SNP) | VAF 51/160 reads (32%) | called by muse, mutect2, varscan2
- PCDH7 | c.1164C>A p.R388= | Silent (SNP) | VAF 115/351 reads (33%) | catalogued as COSV62342343; called by muse, mutect2, varscan2
- PCDHB15 | c.1893C>T p.S631= | Silent (SNP) | VAF 346/1092 reads (32%) | called by muse, mutect2, varscan2
- PCLO | c.10737A>G p.Q3579= | Silent (SNP) | VAF 63/268 reads (24%) | called by muse, mutect2, varscan2
- PDCD7 | c.1047G>A p.T349= | Silent (SNP) | VAF 13/197 reads (7%) | catalogued as rs147295901; called by muse, mutect2
- PDZD4 | c.1893C>T p.D631= | Silent (SNP) | VAF 83/280 reads (30%) | catalogued as COSV51251460; called by muse, mutect2, varscan2
- PHF3 | c.4731A>T p.S1577= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- PHLDB2 | c.525G>A p.S175= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as rs376563651, COSV101208401, COSV67312695; called by muse, mutect2, varscan2
- PIK3AP1 | c.1432C>A p.R478= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as COSV59531507, COSV59531568; called by muse, mutect2, varscan2
- SCNN1B | c.285C>T p.V95= | Silent (SNP) | VAF 58/289 reads (20%) | called by muse, mutect2, varscan2
- SIRPA | c.696C>T p.H232= | Silent (SNP) | VAF 133/672 reads (20%) | catalogued as rs769493586, COSV61537567; called by muse, mutect2, varscan2
- SLC17A9 | c.1095G>A p.P365= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as rs756409472, COSV64848272; called by muse, mutect2, varscan2
- TRIM6 | c.279A>G p.K93= | Silent (SNP) | VAF 97/341 reads (28%) | catalogued as rs139606995; called by muse, mutect2, varscan2
- ZNF433 | c.852T>C p.C284= | Silent (SNP) | VAF 15/289 reads (5%) | called by muse, mutect2
- APPL2 | c.416-10T>C | Intron (SNP) | VAF 44/199 reads (22%) | catalogued as rs369697149; called by muse, mutect2, varscan2
- CCL4L2 | c.191+88G>A | Intron (SNP) | VAF 56/169 reads (33%) | catalogued as rs755259101; called by muse, mutect2, varscan2
- DSCR8 | n.401G>A | RNA (SNP) | VAF 14/150 reads (9%) | catalogued as rs61748275; called by muse, mutect2
- F5 | c.*39G>C | 3'UTR (SNP) | VAF 61/205 reads (30%) | called by muse, mutect2, varscan2
- LILRB5 | c.1630-109G>C | Intron (SNP) | VAF 40/427 reads (9%) | called by muse, mutect2, varscan2
- MIR508 | n.35G>T | RNA (SNP) | VAF 43/166 reads (26%) | called by muse, mutect2, varscan2
- MRPL54 | c.*34G>A | 3'UTR (SNP) | VAF 84/352 reads (24%) | catalogued as rs766782435; called by muse, mutect2, varscan2
- TDRD6 | c.*3G>A | 3'UTR (SNP) | VAF 36/229 reads (16%) | catalogued as rs749611205, COSV51267111; called by muse, mutect2, varscan2
- TPM1 | c.240+4341A>C | Intron (SNP) | VAF 26/215 reads (12%) | called by muse, mutect2, varscan2
